Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7049, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7049-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

History of ocular melanoma right renal mass.

Specimens Submitted:

1: Kidney, right renal tumor, partial nephrectomy

DIAGNOSIS:

1. **Kidney, right renal tumor, partial nephrectomy**

Tumor Type:

Renal cell carcinoma - Papillary type
combined type 1 and type 2, high grade

Tumor Size:

Greatest diameter is 3.2 cm.

Local Invasion (for renal cortical types):

The tumor invades into the capsule, but not extends through.

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

The tumor is within 1 mm to the surgical deep margin.

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: Immunohistochemical study reveals the tumor cells are positive for CK7, racemase; weakly positive for CD10; and focally positive for 34BE12. The findings support our diagnosis.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	34BE12	
	RACEMASE	
	NEG CONT	
	IMM RECUT	
	CK7	
	CD10	

Gross Description:

1) The specimen is received fresh for frozen section, labeled "Right renal tumor" and consists of a partial nephrectomy specimen, measuring 4.2 x 3.3 x 1.5 cm. A stitch marks the deep surface, which is inked, blue, the capsular surface is inked black and the lateral pattern, and margin is inked yellow. The specimen is serially sectioned to reveal a tan white tumor with yellow foci, which measures 3.2 x 2 x 1.8 cm. The tumor abuts the capsule and the deep margin. The uninvolved renal parenchyma is grossly unremarkable. Representative sections are submitted after tumor is submitted for

Summary of sections:

FSC-frozen section control

T-tumor

R-representative renal parenchyma

Summary of Sections:

Part 1: Kidney, right renal tumor, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	r	1
5	t	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. DEEP MARGIN UNINVOLVED.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 37a94ba7-f4d5-443f-93e9-d854ed25092f (TCGA-BQ-7049.5E20C7C8-65A1-45A6-9CA2-5E5C04A5E68F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).